Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7177, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7177-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED], the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (A) TOTAL LARYNGECTOMY AND RIGHT LOBE THYROIDECTOMY:
No cartilage involvement by tumor.

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) TOTAL LARYNGECTOMY AND RIGHT LOBE THYROIDECTOMY:
TOTAL LARYNGECTOMY:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF
SUBGLOTTIS (2.0 CM) INVOLVING BOTH RIGHT AND LEFT
SUBGLOTTIS, SURGICAL MARGINS FREE OF TUMOR.
RIGHT LOBE OF THYROID:
Colloid nodules, no tumor present.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

- (A) TOTAL LARYNGECTOMY AND RIGHT LOBE THYROIDECTOMY - A total laryngectomy and right thyroidectomy with overall measurements of 7.5 x 4.0 x 3.5 cm. The subglottic lesion involving the midline and extending to the right and left subglottis is a light-tan, ulcerated and slightly indurated mass (2.0 x 1.5 x 0.4 cm). The lesion is entirely subglottic and does not appear to extend to the underlying cartilage. The right thyroid mass is 4.0 x 3.5 x 2.0 cm and shows multinodular goiter. The laryngeal mass is submitted entirely from right to left in A1-A9; A10-A12, representative sections of the thyroid nodule.

SNOMED CODES

[page 2 of 2]
M-72032 M-80703 T-24100 T-B6000

Source: NCI Genomic Data Commons file be9d58ee-1b1b-4a2e-9435-ed53298fa015 (TCGA-CV-7177.ECCBC5A9-3528-4178-88E9-208D4A196D92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).